Somatic mutation profile of tumor specimen TCGA-X7-A8M7-01A (aliquot TCGA-X7-A8M7-01A-11D-A423-09) from TCGA case TCGA-X7-A8M7, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 26.9 years (9,815 days).
Specimen TCGA-X7-A8M7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f0c9e70-391c-4591-beb3-76e45fadb6e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8M7-10A (Blood Derived Normal), aliquot TCGA-X7-A8M7-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10cac782-6652-42b1-a95d-391175d5dd82

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRM3 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV55105049; called by muse, mutect2
- CNKSR1 | c.1535del p.P512Hfs*58 (on ENST00000374253 / NM_001297647.2; = p.P505Hfs*58 on NM_006314.3) | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as rs753922055; called by pindel, varscan2
